Gene-level copy-number profile of tumor specimen TCGA-FD-A3B6-01A from TCGA case TCGA-FD-A3B6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.4 years (27,541 days).
Specimen TCGA-FD-A3B6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.64b67047-70c3-48e6-9c9e-1d29450dba18.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3B6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6175eb82-dc25-4219-bc53-a8bff2d5face

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,948; copy number 2: 14,177; copy number 3: 24,694; copy number 4: 11,659; copy number 5: 4,125; copy number 6: 1,919; copy number 7: 235; copy number 8: 399; copy number 9: 99; copy number 10: 115; copy number 11: 210; copy number 12: 92; copy number 17: 2; copy number 20: 10; copy number 21: 27; copy number 22: 26; copy number 26: 30; copy number 33: 42; copy number 41: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3B6-01A-21D-A20B-01): tumor purity 0.42, ploidy 3.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,291 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:115,835,129–115,940,291, 1 gene, copy number 7: AC016721.1.
- chr2:127,798,903–130,145,134, 50 genes, copy number 10–17: RNY4P7, Y_RNA, ZFP91P1, POLR2D, RNU6-395P, RPS26P19, Metazoa_SRP, AMMECR1L, AC012306.2, AC012306.3, AC012306.1, SAP130, AC108059.2, Y_RNA, UGGT1, SRMP3, AC108059.1, DYNLT3P2, RPL14P6, RPL21P34, HS6ST1, Y_RNA, RNA5SP103, ISCA1P6, AC012451.1, AC068483.1, LINC01854, PPIAP65, LINC02572, AC079776.5, PLAC9P1, LINC01856, RPL22P7, RAB6C-AS1, RAB6C, AC079776.3, AC079776.4, AC079776.2, AC079776.1, ARHGAP42P2, FAR2P1, AC018865.2, KLF2P1, CYP4F27P, POTEF, AC018865.1, POTEF-AS1, RNU6-1049P, MED15P9, CCDC74B.
- chr3:88,317,156–90,184,733, 12 genes, copy number 9: ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P.
- chr6:19,837,370–24,809,798, 63 genes, copy number 11–21 (broad region; genes not listed).
- chr7:70,972–8,752,961, 204 genes, copy number 7–8 (broad region; genes not listed).
- chr7:38,317,017–40,860,763, 47 genes, copy number 9 (within-gene range 6–9): TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1.
- chr7:49,850,421–55,955,239, 93 genes, copy number 10–33 (within-gene range 6–33) (broad region; genes not listed).
- chr7:55,951,877–55,956,500, 1 gene, copy number 33: MRPS17.
- chr10:63,664,664–65,315,080, 13 genes, copy number 9 (within-gene range 4–9): AC013287.1, RPL7AP50, AC012558.1, DBF4P1, RPL17P35, CYP2C61P, ANXA2P3, LINC02671, NEK4P3, AL513321.2, MYL6P3, AL513321.1, AL592466.1.
- chr10:68,106,117–81,875,133, 331 genes, copy number 7–11 (broad region; genes not listed).
- chr12:87,944,885–88,142,099, 6 genes, copy number 22 (within-gene range 2–22): RPS4XP15, C12orf50, C12orf29, CEP290, RNA5SP364, AC091516.1.
- chr12:89,282,223–90,300,974, 24 genes, copy number 7–10: RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392.
- chr12:91,423,781–92,929,331, 24 genes, copy number 22–41 (within-gene range 3–41): AC090016.1, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50.
- chr16:27,066,707–27,452,042, 11 genes, copy number 12 (within-gene range 4–12): C16orf82, AC092725.1, EEF1A1P38, LINC02129, KDM8, AC109449.1, NSMCE1, NSMCE1-DT, AC106739.1, IL4R, IL21R.
- chr16:28,341,434–29,370,272, 1 gene, copy number 12 (within-gene range 4–12): AC009093.11.
- chr16:28,532,708–29,731,404, 80 genes, copy number 12 (broad region; genes not listed).
- chr17:14,069,490–15,975,746, 59 genes, copy number 8 (within-gene range 3–8): COX10, SNORA74, CDRT15, AC005224.1, HS3ST3B1, AC005224.3, AC005224.2, AC022816.1, RPS18P12, AC013248.1, AC005863.1, LINC02096, RPL23AP76, AC005772.1, CDRT7, AC005772.2, CDRT8, PMP22, MIR4731, AC005703.5, AC005703.2, AC005703.6, AC005703.1, TEKT3, RNU6-799P, AC005703.4, AC005703.3, RN7SL792P, CDRT4, TVP23C-CDRT4, RPL9P2, TVP23C, PPIAP53, AC005838.2, CDRT1, AC005324.2, SNORA74, AC005838.1, TRIM16, AC005324.4, ZNF29P, ZNF286A, AC005324.3, UBE2SP1, TBC1D26, TBC1D26-AS1, AC005324.5, AC005324.1, CDRT15P2, ZSWIM5P1, RNA5SP436, IL6STP1, MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B.
- chr22:24,952,730–32,498,829, 269 genes, copy number 8–26 (broad region; genes not listed).
- chr22:32,583,300–32,635,198, 2 genes, copy number 8: SYN3-AS1, RNA5SP497.

Autosomal genes at a single copy (total copy number 1): 1,111. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
